Gene-level copy-number profile of tumor specimen HCM-CSHL-0373-C25-01A from HCMI case HCM-CSHL-0373-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G3; Age at diagnosis: 71.9 years (26,274 days).
Specimen HCM-CSHL-0373-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8e15ea6c-5d21-425a-9532-2e3c28d5e199.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0373-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,219 have no estimate.
https://portal.gdc.cancer.gov/files/c39cbeac-e86e-453f-8881-437f77cf364f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 30; copy number 1: 15,615; copy number 2: 42,608; copy number 3: 150; copy number 4: 1.

Homozygous deletions (total copy number 0; autosomes only): 30 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 8 genes (within-gene range 0–1): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes (within-gene range 0–1): AL449423.1, CDKN2B, UBA52P6.
- chr9:39,983,793–40,106,611, 1 gene (within-gene range 0–1): AL772307.1.
- chr9:40,105,822–40,106,527, 1 gene: AL773545.3.
- chr14:105,620,506–105,626,066, 1 gene (within-gene range 0–1): IGHG4.
- chr14:105,639,559–105,673,314, 5 genes (within-gene range 0–1): IGHG2, MIR8071-2, COPDA1, IGHGP, ELK2AP.
- chr14:105,721,794–105,722,527, 1 gene (within-gene range 0–1): IGHEP1.
- chr18:50,959,267–51,643,939, 10 genes (within-gene range 0–1): Y_RNA, ELAC1, AC091551.1, SMAD4, SRSF10P1, MEX3C, RNU1-46P, LINC01630, SS18L2P2, AC109315.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 13,597. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
